Gene-level copy-number profile of tumor specimen TCGA-75-6205-01A from TCGA case TCGA-75-6205, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-6205-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5706c297-61f8-46f9-9fd0-6a9ca627620c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-75-6205-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e51a2c2-0376-4f84-83b5-420901a85289

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,323; copy number 2: 43,354; copy number 3: 8,773; copy number 4: 1,457; copy number 5: 409; copy number 6: 39; copy number 7: 89; copy number 8: 55; copy number 9: 152; copy number 10: 10; copy number 12: 18; copy number 13: 4; copy number 14: 80; copy number 15: 46; copy number 17: 3; copy number 20: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-75-6205-01A-11D-1752-01): tumor purity 0.27, ploidy 1.4, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 912 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–2,715,237, 80 genes, copy number 5–14 (broad region; genes not listed).
- chr5:8,444,949–14,992,961, 105 genes, copy number 8–14 (broad region; genes not listed).
- chr5:16,451,519–26,749,997, 137 genes, copy number 5–17 (broad region; genes not listed).
- chr5:31,053,565–37,753,435, 126 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:38,460,925–43,707,405, 97 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:62,146,665–65,871,725, 42 genes, copy number 7 (within-gene range 3–7): RN7SKP157, KIF2A, AC114982.2, DIMT1, IPO11, RNU6-661P, CKS1BP3, AC114982.1, RPL35AP14, LRRC70, ISCA1P1, AC113420.1, AC025445.1, AC008558.1, HTR1A, AC122707.1, RNF180, AC091862.1, RGS7BP, RN7SL169P, RNU6-294P, MRPL49P1, SHISAL2B, SREK1IP1, CWC27, AC092354.2, AC092354.1, Y_RNA, ADAMTS6, AC008868.1, RPEP1, AC025186.1, AC025176.1, CENPK, PPWD1, TRIM23, RNU6-540P, TRAPPC13, SHLD3, SGTB, NLN, AC008958.1.
- chr5:81,201,341–86,800,280, 73 genes, copy number 8–12 (within-gene range 2–12) (broad region; genes not listed).
- chr8:101,034,868–101,372,707, 16 genes, copy number 5–17: FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2.
- chr8:106,980,967–108,787,594, 20 genes, copy number 6 (within-gene range 3–6): AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1.
- chr8:121,380,137–126,008,930, 88 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr8:125,900,951–125,901,054, 1 gene, copy number 5: RNU6-442P.
- chr8:127,578,473–128,564,679, 18 genes, copy number 12–15: AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:130,780,301–133,963,259, 43 genes, copy number 7–20: ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2.
- chr8:135,457,456–140,638,283, 32 genes, copy number 5–15 (within-gene range 4–15): KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD.
- chr8:142,727,223–143,368,548, 34 genes, copy number 9: THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1, CYP11B1, CYP11B2, LY6E-DT, CDC42P3, LY6E, C8orf31, AK3P2, AC083982.1, LY6L, LY6H, GPIHBP1, ZFP41, AC138696.1, GLI4, MINCR, ZNF696, AC138696.2, TOP1MT, RNU6-220P, RHPN1-AS1.

Autosomal genes at a single copy (total copy number 1): 3,617. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
